Somatic mutation profile of tumor specimen TCGA-VS-A8EG-01A (aliquot TCGA-VS-A8EG-01A-11D-A36J-09) from TCGA case TCGA-VS-A8EG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: GX; Age at diagnosis: 36.0 years (13,166 days).
Specimen TCGA-VS-A8EG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f212b183-eaee-4e17-8267-6e09e530e12c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EG-10A (Blood Derived Normal), aliquot TCGA-VS-A8EG-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bdfcd3a-feaa-4583-864e-885c2e75a9cc

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as rs779626155, COSV53041751, COSV53073691; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 82/133 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTR3B | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1184102995, COSV99753958; called by muse, mutect2, varscan2
- ANO9 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs139380371; called by muse, mutect2, varscan2
- CACNA1D | c.4864C>T p.R1622W (on ENST00000350061 / NM_001128840.3; = p.R1642W on NM_000720.4) | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145414503; called by muse, mutect2, varscan2
- CD226 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs375997671; called by muse, mutect2, varscan2
- CNTNAP4 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371162409, COSV56706368; called by muse, mutect2
- COL15A1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV66648533; called by muse, mutect2, varscan2
- DIS3L | c.586T>A p.L196I (on ENST00000319212 / NM_001143688.3; = p.L113I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs750469259, COSV100055176; called by muse, mutect2, varscan2
- GRK7 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs949959698, COSV99379814; called by muse, mutect2, varscan2
- HARS1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100298006; called by muse, mutect2, varscan2
- KCNC4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as COSV100873611, COSV63925558; called by muse, mutect2, varscan2
- KCNQ4 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs373405864; called by muse, mutect2
- KIAA0930 | c.179C>T p.A60V (on ENST00000336156 / NM_001009880.2; = p.A65V on NM_015264.2) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.255); catalogued as rs762931184, COSV52662455; called by muse, mutect2, varscan2
- KIF7 | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs372979006; called by muse, mutect2, varscan2
- KLHL21 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs760923196, COSV66553552; called by muse, mutect2, varscan2
- MAGEC1 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99595569; called by muse, mutect2, varscan2
- NFASC | c.2677G>A p.V893M (on ENST00000339876 / NM_001378329.1; = p.V996M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377519786; called by muse, mutect2, varscan2
- NRBP2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs146279016; called by muse, mutect2, varscan2
- PCDHB15 | c.1390A>T p.N464Y | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99178904; called by muse, mutect2, varscan2
- PRUNE2 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756849942, COSV100944505; called by muse, mutect2, varscan2
- PTPN18 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV99447726; called by muse, mutect2, varscan2
- RAB5B | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100822143; called by muse, mutect2, varscan2
- RPTN | c.1396A>C p.T466P | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs994306380, COSV60166619; called by muse, mutect2, varscan2
- SLC9C1 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs756267726, COSV59888899; called by muse, mutect2, varscan2
- SPTY2D1 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100311643; called by muse, mutect2, varscan2
- TXLNB | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV64444403; called by muse, mutect2, varscan2
- UBE2E3 | c.121_123del p.S41del | In Frame Del (DEL) | VAF 38/97 reads (39%) | catalogued as rs1488771682; called by mutect2, pindel, varscan2
- UBXN11 | c.676C>T p.R226W (on ENST00000374221 / NM_183008.2; = p.R193W on NM_145345.2) | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs566971320, COSV99582190; called by muse, mutect2, varscan2
- ZNF516 | c.2641G>A p.G881S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs754048310, COSV101487269; called by muse, mutect2, varscan2
- MYH9 | c.4670_4673delinsA p.R1557_L1558delinsQ | In Frame Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2*
- PEX6 | c.689_690del p.E230Vfs*11 | Frame Shift Del (DEL) | VAF 40/70 reads (57%) | called by pindel, varscan2
- SCYL2 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.04); called by muse, mutect2
- ADAMTS17 | c.1386G>A p.P462= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs565893965, COSV51497077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C8orf34 | c.1575T>A p.V525= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100446068; called by muse, mutect2, varscan2
- CAND1 | c.2292C>T p.V764= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101607315; called by muse, mutect2, varscan2
- DNAH9 | c.2583C>T p.H861= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs759701988, COSV99305615; called by muse, mutect2, varscan2
- ERICH1 | c.144C>T p.S48= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs1258262450, COSV50638477; called by muse, mutect2, varscan2
- KRT3 | c.1020C>T p.D340= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs150031039; called by muse, mutect2, varscan2
- MTMR1 | c.366A>T p.A122= | Silent (SNP) | VAF 73/225 reads (32%) | catalogued as COSV100953926; called by muse, mutect2, varscan2
- PEX5L | c.1384C>T p.L462= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99828537; called by muse, mutect2, varscan2
- PHF13 | c.234G>A p.A78= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs751868551, COSV99275654; called by muse, mutect2, varscan2
- PTGS1 | c.525C>G p.L175= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs185705486, COSV99793135; called by muse, mutect2, varscan2
- SPATA21 | c.576C>T p.Y192= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs376499162; called by muse, mutect2, varscan2
- TNS4 | c.1773C>T p.S591= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs530289976, COSV54187225, COSV99563794; called by muse, mutect2, varscan2
